Somatic mutation profile of tumor specimen 0DU1XA from CCDI case PBCKFV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Glioma, malignant; Tissue or organ of origin: Parietal lobe; Age at diagnosis: 13.6 years (4,978 days).
Specimen 0DU1XA: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f0de3b1b-956f-4335-98f9-e4a42a92a123.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DU1W8 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bde7aa55-d4fd-4064-9977-0e33272673a9

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Missense Mutation 3.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C11orf96 | c.1067G>A p.G356D (on ENST00000339446; = p.G43D on NM_001145033.2) | Missense Mutation (SNP) | VAF 92/793 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- CCL13 | c.252T>A p.N84K | Missense Mutation (SNP) | VAF 46/592 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.14); called by muse, mutect2
- TOP2B | c.3661G>A p.G1221S (on ENST00000264331 / NM_001330700.2; = p.G1216S on NM_001068.3) | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.005); called by muse, mutect2
